Somatic mutation profile of tumor specimen 92c1ebb5-ac1d-4bf5-a14f-516e1d (aliquot 92c1ebb5-ac1d-4bf5-a14f-516e1d_D6_2) from CPTAC case 05CO045, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen 92c1ebb5-ac1d-4bf5-a14f-516e1d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1466475-b758-4a76-911d-f873583f46f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 8d0e2230-208e-43d7-8048-73d6d6 (Blood Derived Normal), aliquot 8d0e2230-208e-43d7-8048-73d6d6_D1_2; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b7e45fe-d704-432c-8427-18b101c843ac

The open-access MAF lists 213 somatic variants for this specimen: 148 protein-altering or splice-affecting, 41 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 41, Intron 12, Nonsense Mutation 11, RNA 5, Splice Site 4, Frame Shift Del 4, 5'Flank 3, 5'UTR 3, Splice Region 2, Frame Shift Ins 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3916G>T p.E1306* | Nonsense Mutation (SNP) | VAF 65/356 reads (18%) | catalogued as rs121913462, CM077502, COSV57322511, COSV57366061, COSV57375983; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 70/197 reads (36%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN11A | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138607170, CM1311119, COSV56575626; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 120/255 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs587782705, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACO2 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.024); catalogued as rs749611259, COSV53445111; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AFF3 | c.1185C>T p.S395= | Splice Region (SNP) | VAF 18/96 reads (19%) | catalogued as rs749008976; called by muse, varscan2
- ALDH3B2 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200176520, COSV100823959; called by muse, mutect2, varscan2
- AQP9 | c.302A>T p.K101I | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54971954; called by muse, mutect2, varscan2
- ARHGAP15 | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.415); catalogued as rs1469222246; called by muse, mutect2, varscan2
- ASTN2 | c.1553C>T p.T518M (on ENST00000313400 / NM_001365069.1; = p.T467M on NM_014010.5) | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs757402722; called by muse, mutect2, varscan2
- ATP2B3 | c.3365G>A p.R1122H (on ENST00000263519 / NM_001001344.2; = p.P1173= on NM_021949.3) | Missense Mutation (SNP) | VAF 119/322 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.077); catalogued as rs142573189, COSV54842847; called by muse, mutect2, varscan2
- CA10 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146043972; called by muse, mutect2, varscan2
- CACNA1E | c.6154C>T p.R2052W (on ENST00000367573 / NM_001205293.3; = p.R2009W on NM_000721.4) | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs768597410, COSV62398227; called by muse, mutect2
- CASP5 | c.533dup p.N178Kfs*3 | Frame Shift Ins (INS) | VAF 35/108 reads (32%) | catalogued as rs765105588; called by mutect2, varscan2
- CCM2L | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs138375629; called by muse, varscan2
- CDH20 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 88/199 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.845); catalogued as rs1168994858, COSV53017004; called by muse, mutect2, varscan2
- CDKL5 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.675); catalogued as COSV101184030; called by muse, varscan2
- CFAP97D1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs775180011; called by muse, mutect2, varscan2
- CNTNAP2 | c.2699G>A p.R900Q | Missense Mutation (SNP) | VAF 81/286 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs374321266; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA2 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV58169619; called by muse, mutect2, varscan2
- CTNNB1 | c.1955-1G>A p.X652_splice | Splice Site (SNP) | VAF 44/551 reads (8%) | catalogued as COSV62691011; called by muse, mutect2
- CUX2 | c.2377C>T p.R793C | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs773164638, COSV55625222; called by muse, varscan2
- CYSLTR1 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 115/324 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200535935; called by muse, mutect2, varscan2
- DCAF12L2 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 162/416 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.34); catalogued as COSV100758530; called by muse, varscan2
- DCBLD2 | c.2128C>T p.P710S | Missense Mutation (SNP) | VAF 30/362 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV54583800; called by muse, mutect2
- DNAH14 | c.1316G>A p.R439H (on ENST00000445597; = p.R420H on NM_001145154.3) | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs889773123; called by muse, mutect2, varscan2
- DSCAM | c.3649G>A p.G1217S | Missense Mutation (SNP) | VAF 71/149 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs781757299; called by muse, mutect2, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 78/242 reads (32%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, varscan2
- EGFR | c.2311_2313dup p.N771dup | In Frame Ins (INS) | VAF 186/518 reads (36%) | catalogued as COSV51766549, COSV51779915, COSV51787954, COSV51807227, COSV51814184, COSV51816337, COSV51859791; called by mutect2, varscan2
- EPHA10 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 83/166 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs192256218, COSV57624285, COSV57624396; called by muse, mutect2, varscan2
- EXOC3 | c.1938C>T p.S646= | Splice Region (SNP) | VAF 32/188 reads (17%) | catalogued as rs565374942; called by muse, mutect2, varscan2
- FBN1 | c.2078G>A p.G693E | Missense Mutation (SNP) | VAF 106/504 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771202007; called by muse, mutect2, varscan2
- FLG | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 66/683 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.334); catalogued as rs779690124, COSV64239340; called by muse, mutect2, varscan2
- GIPC3 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); catalogued as rs754612636; called by muse, mutect2, varscan2
- GPR101 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1286618570; called by muse, mutect2
- GRAMD1C | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 21/106 reads (20%) | catalogued as rs199701091, COSV63981732; called by muse, mutect2, varscan2
- GRIN3B | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs151255899; called by muse, mutect2, varscan2
- H1-5 | c.615_629del p.P213_K217del | In Frame Del (DEL) | VAF 19/58 reads (33%) | catalogued as rs758100284; called by mutect2, varscan2
- HCN1 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 77/222 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV100298868, COSV100302935; called by muse, mutect2, varscan2
- HMCN2 | c.14546G>T p.W4849L | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.961); catalogued as rs778458084; called by muse, mutect2, varscan2
- HRH2 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 64/336 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1165300612, COSV51572677; called by muse, mutect2, varscan2
- IL1RAPL1 | c.362G>A p.R121K | Missense Mutation (SNP) | VAF 9/244 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV56242883; called by muse, mutect2
- ITIH5 | c.1780G>A p.D594N | Missense Mutation (SNP) | VAF 62/297 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs150174865; called by muse, mutect2, varscan2
- KCNT2 | c.2990G>A p.R997H | Missense Mutation (SNP) | VAF 33/312 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs781172493, COSV54063065; called by muse, mutect2, varscan2
- KHDC3L | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as COSV64859131, COSV64859608; called by muse, mutect2, varscan2
- KMT2D | c.10090C>A p.Q3364K | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs1210590639, CM138445; called by muse, mutect2, varscan2
- KRT12 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 135/653 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as rs1162103556; called by muse, mutect2, varscan2
- LOXHD1 | c.2614G>A p.V872M | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1045162755; called by muse, mutect2
- LRBA | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1467585610; called by muse, mutect2, varscan2
- MAP7D3 | c.1082C>A p.S361Y | Missense Mutation (SNP) | VAF 74/960 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.097); catalogued as rs1215996297, COSV60170128; called by muse, mutect2
- MED1 | c.3367_3369del p.S1125del | In Frame Del (DEL) | VAF 76/276 reads (28%) | catalogued as rs1325398652; called by pindel, varscan2
- MYOT | c.301T>G p.L101V | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs1446632768; called by muse, mutect2, varscan2
- NEK1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs191859401; called by muse, mutect2, varscan2
- NLRP11 | c.2471C>T p.T824M | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.129); catalogued as rs374529395; called by muse, mutect2, varscan2
- NLRP2 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 25/175 reads (14%) | catalogued as COSV99672438; called by muse, mutect2, varscan2
- NPFFR2 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV100440646; called by muse, mutect2, varscan2
- PAPPA2 | c.2672G>A p.R891H | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs769584951, COSV100867259, COSV62772532; called by muse, mutect2, varscan2
- PCDHA6 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 62/350 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs782549490; called by muse, mutect2, varscan2
- PCDHGB2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs763145950; called by muse, mutect2, varscan2
- PGBD5 | c.247C>T p.R83W (on ENST00000525115; = p.R152W on NM_001258311.2) | Missense Mutation (SNP) | VAF 43/496 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs561944260; called by muse, mutect2
- PHF2 | c.2717C>T p.P906L | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1441064874, COSV100823266; called by muse, mutect2, varscan2
- PHTF1 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as rs200552382, COSV63367842; called by muse, mutect2, varscan2
- PRAM1 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.741); catalogued as rs750049106, COSV55315199; called by muse, mutect2, varscan2
- PRSS12 | c.1561del p.W521Gfs*16 | Frame Shift Del (DEL) | VAF 58/362 reads (16%) | catalogued as COSV56610951; called by pindel, varscan2
- PRSS45P | c.112G>C p.G38R | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs1204323135; called by muse, mutect2
- RHOXF2 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 148/633 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs782207635; called by muse, mutect2, varscan2
- RIPK1 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.361); catalogued as rs755668565; called by muse, mutect2, varscan2
- RLF | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs763434695, COSV101035103; called by muse, mutect2, varscan2
- RPS6KB2 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 117/310 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs763667411, COSV57051572; called by muse, mutect2, varscan2
- SCN1A | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as rs769582667, COSV57660030; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIRT4 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.233); catalogued as rs201091007; called by muse, mutect2
- SLC16A2 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 38/786 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV52088760; called by muse, mutect2
- STAG1 | c.2303C>T p.T768M | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs757065909; called by muse, mutect2
- STARD6 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs769379736, COSV57141991; called by muse, mutect2, varscan2
- TACC2 | c.7849G>A p.E2617K (on ENST00000334433; = p.E695K on NM_006997.4) | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV53278790; called by muse, mutect2, varscan2
- TARM1 | c.259G>A p.A87T (on ENST00000616041 / NM_001330650.1; = p.A79T on NM_001135686.3) | Missense Mutation (SNP) | VAF 106/280 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.079); catalogued as rs587693682, COSV71524765; called by muse, varscan2
- TENM4 | c.8038G>A p.G2680R | Missense Mutation (SNP) | VAF 139/375 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768500242; called by muse, mutect2, varscan2
- TIE1 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as rs760739342; called by muse, varscan2
- TNNT1 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 39/333 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as rs1243419099; called by muse, mutect2, varscan2
- TRIM41 | c.1642dup p.E548Gfs*27 | Frame Shift Ins (INS) | VAF 79/420 reads (19%) | catalogued as rs1286926685; called by mutect2, varscan2
- TRMT1 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.189); catalogued as rs1363187627; called by muse, mutect2, varscan2
- TRPS1 | c.827C>G p.S276C (on ENST00000220888 / NM_001330599.2; = p.S289C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.949); catalogued as COSV55241197; called by muse, mutect2, varscan2
- TSPYL2 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 32/436 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV60233694; called by muse, mutect2
- TTC17 | c.3061G>A p.A1021T | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV50018639; called by muse, mutect2, varscan2
- TTC28 | c.4627G>A p.V1543I | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as rs574415063; called by muse, mutect2
- TTN | c.45467G>A p.R15156H (on ENST00000591111; = p.R7732H on NM_003319.4) | Missense Mutation (SNP) | VAF 11/139 reads (8%) | PolyPhen probably damaging (0.998); catalogued as rs200835354; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2
- WDR5 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1166495649, COSV62272843; called by muse, mutect2, varscan2
- YEATS2 | c.3022G>A p.A1008T | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV59364433; called by muse, mutect2, varscan2
- ZNF512B | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 182/494 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1569196492; called by muse, mutect2
- ZNF568 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61741345; called by muse, mutect2
- ZNF728 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs751059458, COSV74099300, COSV74099462; called by mutect2, varscan2
- ZNF776 | c.1440G>T p.Q480H | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV57816776; called by mutect2, varscan2
- ANKRD31 | c.3274del p.T1092Qfs*12 | Frame Shift Del (DEL) | VAF 98/232 reads (42%) | called by mutect2, varscan2
- ARID4A | c.475A>G p.S159G | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- ATRX | c.2887G>T p.D963Y | Missense Mutation (SNP) | VAF 99/238 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- BPIFA3 | c.715C>A p.H239N | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2
- BRF2 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CCDC33 | c.635T>G p.F212C | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CEP126 | c.1472C>A p.S491Y | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CPXCR1 | c.725T>C p.I242T | Missense Mutation (SNP) | VAF 19/422 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- CREB3L1 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 37/491 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); called by muse, mutect2
- CRTAC1 | c.716-1G>A p.X239_splice | Splice Site (SNP) | VAF 31/174 reads (18%) | called by muse, mutect2, varscan2
- CUL7 | c.1530G>T p.Q510H | Missense Mutation (SNP) | VAF 214/440 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- CYP7B1 | c.903G>T p.M301I | Missense Mutation (SNP) | VAF 83/560 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- DAAM2 | c.228G>T p.K76N | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EML4 | c.1984G>A p.A662T | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT4 | c.11552A>C p.K3851T | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2
- FBXO27 | c.639G>T p.Q213H | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.527); called by muse, mutect2
- FLT3 | c.2473G>A p.V825M | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- FOXK2 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GLRA2 | c.494+1G>A p.X165_splice | Splice Site (SNP) | VAF 174/539 reads (32%) | called by muse, mutect2, varscan2
- GNAQ | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GP5 | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 165/314 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- GRIA3 | c.1121C>G p.T374S | Missense Mutation (SNP) | VAF 80/340 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIA4 | c.328T>A p.C110S | Missense Mutation (SNP) | VAF 14/339 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.353); called by muse, mutect2
- KIF1B | c.2658G>T p.W886C (on ENST00000377086 / NM_001365952.1; = p.W840C on NM_015074.3) | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LIN7B | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LIPE | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 11/377 reads (3%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.575); called by muse, mutect2
- LRIG3 | c.2574G>T p.L858F | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- MAML2 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 112/264 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAPKBP1 | c.999-2A>G p.X333_splice (on ENST00000456763 / NM_001128608.2; = p.X327_splice on NM_014994.3) | Splice Site (SNP) | VAF 30/87 reads (34%) | called by muse, mutect2, varscan2
- MED12L | c.1768G>T p.E590* | Nonsense Mutation (SNP) | VAF 29/163 reads (18%) | called by muse, mutect2, varscan2
- MUC16 | c.20216C>A p.T6739K | Missense Mutation (SNP) | VAF 75/226 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- OR5M8 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PDS5B | c.3254T>A p.L1085* | Nonsense Mutation (SNP) | VAF 16/120 reads (13%) | called by muse, mutect2, varscan2
- PNOC | c.150G>T p.E50D | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- POLA1 | c.3445A>G p.K1149E | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- PPP3CA | c.968A>C p.K323T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- PRPF40A | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- PRR5 | c.684C>A p.C228* (on ENST00000336985 / NM_181333.4; = p.C219* on NM_015366.4) | Nonsense Mutation (SNP) | VAF 19/116 reads (16%) | called by muse, mutect2, varscan2
- PTOV1 | c.1231C>T p.Q411* | Nonsense Mutation (SNP) | VAF 77/420 reads (18%) | called by muse, mutect2, varscan2
- PTPRQ | c.2186C>A p.S729* (on ENST00000616559; = p.S687* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 86/215 reads (40%) | called by muse, mutect2, varscan2
- RHOBTB1 | c.517A>G p.K173E | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- RNF180 | c.1382C>G p.A461G | Missense Mutation (SNP) | VAF 90/298 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- SLITRK1 | c.1750A>T p.R584W | Missense Mutation (SNP) | VAF 107/695 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPEG | c.8618A>G p.K2873R | Missense Mutation (SNP) | VAF 63/347 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- SPIRE1 | c.869A>G p.Q290R | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SUFU | c.558G>T p.Q186H | Missense Mutation (SNP) | VAF 14/351 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- SUPT6H | c.224_225del p.S75Wfs*2 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | called by pindel, varscan2
- TMEM169 | c.71C>A p.A24D | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.155); called by muse, varscan2
- UGT3A1 | c.132G>T p.Q44H | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- UMAD1 | c.237C>A p.S79R | Missense Mutation (SNP) | VAF 75/250 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- UNC45B | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- VCX | c.94A>C p.K32Q | Missense Mutation (SNP) | VAF 40/784 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); called by muse, mutect2
- VCX2 | c.128A>G p.K43R | Missense Mutation (SNP) | VAF 25/299 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- VWC2L | c.406T>C p.W136R | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF430 | c.921T>G p.H307Q | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- ZNF443 | c.470A>G p.Q157R | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.029); called by muse, mutect2
- ACACB | c.129G>A p.P43= | Silent (SNP) | VAF 55/125 reads (44%) | catalogued as rs146888683; called by muse, mutect2, varscan2
- ADGRE5 | c.1134C>T p.S378= (on ENST00000242786 / NM_078481.4; = p.S285= on NM_001784.5) | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs756516696, COSV99662689; called by muse, mutect2, varscan2
- ANKRD44 | c.1332T>C p.Y444= | Silent (SNP) | VAF 37/109 reads (34%) | called by muse, mutect2, varscan2
- ATP13A4 | c.1503C>T p.V501= | Silent (SNP) | VAF 18/168 reads (11%) | catalogued as rs747790751; called by muse, mutect2
- CAVIN1 | c.1053C>T p.G351= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as rs374317281; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCN4 | c.444C>T p.D148= | Silent (SNP) | VAF 108/638 reads (17%) | catalogued as rs755626224, COSV51532431, COSV51535531; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLCN4 | c.2052G>A p.P684= | Silent (SNP) | VAF 153/621 reads (25%) | catalogued as rs777620754, COSV66467568; called by muse, mutect2, varscan2
- COL9A3 | c.999C>T p.N333= | Silent (SNP) | VAF 167/647 reads (26%) | catalogued as rs531882222; called by muse, mutect2, varscan2
- FADS2 | c.816G>A p.P272= | Silent (SNP) | VAF 40/273 reads (15%) | catalogued as rs779599111; called by muse, mutect2, varscan2
- FREM2 | c.8118C>T p.Y2706= | Silent (SNP) | VAF 112/341 reads (33%) | catalogued as rs748692884, COSV54851874; called by muse, mutect2, varscan2
- GPR108 | c.918T>C p.S306= (on ENST00000264080 / NM_001080452.1; = p.S64= on NM_020171.2) | Silent (SNP) | VAF 24/166 reads (14%) | called by muse, mutect2, varscan2
- GPR78 | c.342C>T p.Y114= | Silent (SNP) | VAF 21/134 reads (16%) | catalogued as rs1454537808; called by muse, mutect2, varscan2
- GUCY1A1 | c.561C>T p.D187= | Silent (SNP) | VAF 32/204 reads (16%) | catalogued as rs377376145; called by muse, mutect2, varscan2
- HIVEP3 | c.1383G>T p.V461= | Silent (SNP) | VAF 29/182 reads (16%) | called by muse, mutect2, varscan2
- HS3ST3A1 | c.735G>A p.P245= | Silent (SNP) | VAF 58/363 reads (16%) | catalogued as rs765338942, COSV52373458; called by muse, mutect2, varscan2
- HS3ST3B1 | c.690G>A p.P230= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as rs148382819; called by muse, mutect2, varscan2
- KANK2 | c.165G>A p.K55= | Silent (SNP) | VAF 50/168 reads (30%) | called by mutect2, varscan2
- KLHL34 | c.387G>A p.E129= | Silent (SNP) | VAF 21/591 reads (4%) | called by muse, mutect2
- KLK3 | c.39G>A p.T13= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as rs751400607; called by muse, mutect2, varscan2
- LRRIQ1 | c.3936C>A p.I1312= | Silent (SNP) | VAF 20/302 reads (7%) | catalogued as rs1005717220; called by muse, mutect2
- MCF2L | c.3225C>T p.R1075= (on ENST00000375608; = p.R1043= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/223 reads (30%) | catalogued as rs763823250; called by muse, mutect2, varscan2
- MICAL2 | c.4411C>A p.R1471= | Silent (SNP) | VAF 11/226 reads (5%) | catalogued as COSV56288092; called by muse, mutect2
- PCDHA3 | c.1176C>T p.H392= | Silent (SNP) | VAF 174/478 reads (36%) | catalogued as COSV63545415; called by muse, mutect2, varscan2
- PDGFC | c.798C>T p.T266= | Silent (SNP) | VAF 74/340 reads (22%) | catalogued as rs999173362, COSV56851530; called by muse, varscan2
- PLXNA4 | c.201C>T p.A67= | Silent (SNP) | VAF 139/383 reads (36%) | catalogued as rs751042409, COSV58153553; called by muse, mutect2, varscan2
- PPDPF | c.195C>T p.L65= | Silent (SNP) | VAF 166/464 reads (36%) | catalogued as rs367820531; called by muse, mutect2, varscan2
- PPY | c.33G>T p.L11= | Silent (SNP) | VAF 17/284 reads (6%) | catalogued as rs764976336; called by muse, mutect2
- PRR18 | c.717G>A p.L239= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, varscan2
- PTF1A | c.72C>T p.D24= | Silent (SNP) | VAF 57/125 reads (46%) | catalogued as rs1445527891, COSV64735052; called by muse, mutect2, varscan2
- PXN | c.504C>T p.N168= | Silent (SNP) | VAF 33/105 reads (31%) | called by muse, mutect2, varscan2
- RAPGEFL1 | c.1551C>T p.A517= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as rs913996101; called by muse, mutect2, varscan2
- SERPINA10 | c.414C>T p.P138= | Silent (SNP) | VAF 104/218 reads (48%) | catalogued as rs770457875, COSV56228536; called by muse, mutect2, varscan2
- SLC28A1 | c.1434G>A p.A478= | Silent (SNP) | VAF 166/500 reads (33%) | catalogued as rs370352848; called by muse, mutect2, varscan2
- SLIT1 | c.2964G>A p.P988= | Silent (SNP) | VAF 54/142 reads (38%) | catalogued as rs142876636; called by muse, mutect2, varscan2
- SLX4 | c.2517C>T p.H839= | Silent (SNP) | VAF 166/400 reads (42%) | catalogued as rs766929821, COSV99567498; called by muse, mutect2, varscan2
- STEAP1B | c.489C>T p.Y163= | Silent (SNP) | VAF 142/312 reads (46%) | catalogued as rs571881121, COSV101303713, COSV68345818; called by muse, varscan2
- TMPRSS5 | c.768T>A p.A256= | Silent (SNP) | VAF 43/112 reads (38%) | called by muse, mutect2, varscan2
- TRIP12 | c.1629G>A p.L543= | Silent (SNP) | VAF 25/67 reads (37%) | called by muse, mutect2, varscan2
- TTC28 | c.5983C>T p.L1995= | Silent (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- UPK3B | c.744C>G p.L248= (on ENST00000257632; = p.S220C on NM_001347684.2) | Silent (SNP) | VAF 113/288 reads (39%) | catalogued as COSV57537570; called by muse, mutect2, varscan2
- XPNPEP2 | c.1815G>T p.L605= | Silent (SNP) | VAF 44/416 reads (11%) | catalogued as COSV64370519; called by muse, mutect2
- C15orf61 | c.346+471C>T | Intron (SNP) | VAF 19/177 reads (11%) | called by muse, mutect2, varscan2
- C9orf62 | n.491C>T | RNA (SNP) | VAF 27/210 reads (13%) | called by muse, mutect2, varscan2
- CCDC66 | c.102+1680G>T | Intron (SNP) | VAF 29/87 reads (33%) | called by mutect2, varscan2
- DLX6 | c.437-25G>A | Intron (SNP) | VAF 65/478 reads (14%) | called by muse, mutect2, varscan2
- DOCK8 | c.741+133G>T | Intron (SNP) | VAF 82/266 reads (31%) | catalogued as rs775366988; called by muse, mutect2, varscan2
- EXOG | n.1468A>C | RNA (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- FAM193B | c.1275+1129G>A | Intron (SNP) | VAF 56/237 reads (24%) | catalogued as rs1214317146; called by muse, mutect2, varscan2
- FLNA | c.-8G>A | 5'UTR (SNP) | VAF 28/188 reads (15%) | catalogued as rs1427699055, COSV100774266; called by muse, mutect2, varscan2
- IDO2 | c.-55G>A | 5'UTR (SNP) | VAF 28/94 reads (30%) | catalogued as COSV100584782; called by muse, mutect2, varscan2
- LINC01621 | n.237A>C | RNA (SNP) | VAF 43/70 reads (61%) | called by muse, mutect2, varscan2
- LINC02860 | n.1019C>T | RNA (SNP) | VAF 10/250 reads (4%) | called by muse, mutect2
- MDH1B | c.1409-260C>A | Intron (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1099717 C>T | 5'Flank (SNP) | VAF 20/114 reads (18%) | catalogued as rs564365794; called by muse, mutect2, varscan2
- NRG1 | chr8:31639309 C>T | 5'Flank (SNP) | VAF 30/141 reads (21%) | catalogued as rs780695727; called by muse, mutect2, varscan2
- NRP1 | c.1614+52C>A | Intron (SNP) | VAF 131/364 reads (36%) | called by muse, mutect2, varscan2
- PPM1N | c.939+22A>G | Intron (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- RNF170 | c.-19C>A | 5'UTR (SNP) | VAF 17/188 reads (9%) | catalogued as rs1019476932; called by muse, mutect2
- SPTAN1 | c.4759-19dup | Intron (INS) | VAF 14/113 reads (12%) | catalogued as rs1242511726; called by mutect2, pindel, varscan2
- SSPOP | n.1409G>A | RNA (SNP) | VAF 28/468 reads (6%) | catalogued as rs761863381, COSV50489322; called by muse, mutect2
- TNP1 | c.*27G>A | 3'UTR (SNP) | VAF 46/138 reads (33%) | catalogued as rs374598465, COSV99378621; called by muse, mutect2, varscan2
- TPK1 | c.613+17373C>T | Intron (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2
- TSLP | chr5:111071487 A>G | 5'Flank (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- WASHC4 | c.2759-15dup | Intron (INS) | VAF 40/108 reads (37%) | catalogued as rs753918902; called by mutect2, varscan2
- WDR49 | c.487-6615C>T | Intron (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
